Somatic mutation profile of tumor specimen TCGA-RT-A6YC-01A (aliquot TCGA-RT-A6YC-01A-12D-A35D-08) from TCGA case TCGA-RT-A6YC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.7 years (11,572 days).
Specimen TCGA-RT-A6YC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba216e04-20fc-4ec7-8763-ec395e87b27e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RT-A6YC-10B (Blood Derived Normal), aliquot TCGA-RT-A6YC-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fa8156f-c0db-4d79-8c00-a10839dc66b9

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, RNA 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EVPL | c.4225G>A p.V1409M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs376290291; called by muse, mutect2, varscan2
- SACM1L | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1181029098, COSV66615209; called by muse, mutect2, varscan2
- H2AC1 | c.229dup p.T77Nfs*15 | Frame Shift Ins (INS) | VAF 33/91 reads (36%) | called by mutect2, varscan2
- NFYB | c.240A>G p.K80= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- MIR548A1 | n.80T>A | RNA (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
